Surgical pathology report (de-identified scan), TCGA case TCGA-77-8136, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8136-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

HISTORY

Left pneumonectomy plus lymph node biopsies.

[Note previous cytology from [REDACTED] Bronchial brushings showing atypia suspicious for malignancy; bronchial washings negative.]

MACROSCOPIC

Three specimens received.

1: The specimen is labelled "left pneumonectomy" and consists of a left lung which measures 240 mm from the apex to the base, 165 mm from posterior to anterior and up to 50 mm from lateral to medial. It weighs 343 g. The hilum is distorted by a large tumour nodule which appears to involve both the apical segment of the lower lobe and the superior lingular segment of the upper lobe. Mucopus protrudes from the bronchial resection margin and anteroinferior to this margin there is a small firm nodule which may represent an involved lymph node. The mediastinal pleural surface has a nodular appearance but elsewhere the surface is smooth. Sectioning of the tumour reveals that it invades the bronchial wall and projects within the lumen of the bronchus proximally towards the margin. Tumour is present 11 mm from the bronchial resection margin. The lesion measures 65 x 60 x 40 mm. The centre of the lesion is necrotic and liquid but elsewhere the tumour has a firm variegated cut surface with areas of cream, yellow and tan discolouration. The lesion abuts the overlying mediastinal pleural surface. Extending from the tumour and into the lower lobe there is an area of firm yellow discolouration which is demarcated along one edge by interlobular septa. It extends over an area measuring 55 x 30 x 30 mm and lies beneath the pleura along the anterior border of the lower lobe. This area ends distally at a small 10 cm nodule which has a yellow focally haemorrhagic cut surface. This nodule measures 12 mm in maximum extent. The remaining lung parenchyma is otherwise unremarkable. [1A, bronchial, vascular and soft tissue resection margin; 1B, peribronchial lymph nodes; 1C-1D, endobronchial tumour and adjacent lung; 1E-1F, tumour with overlying mediastinal pleura; 1G, area of yellow consolidation; 1H, distal nodule; 1I, uninvolved apical lung parenchyma.]

2: The specimen is labelled "hilar node" and consists of a single fragment of reddish black tissue which measures 24 x 15 x up to 10 mm. [Bisected, 2A.]

3: The specimen is labelled "No. 8 lymph node" and consists of a single fragment of fibrofatty tissue which measures 20 x 15 x 10 mm. Sectioning reveals a blackened lymph node. [Bisected, 3A.]

MICROSCOPIC

1: Sections show a non-small cell carcinoma with multifocal necrosis. The majority of the tumour comprises patternless sheets of smallish cells with granular chromatin and somewhat fibrillar or granular eosinophilic cytoplasm.

[page 2 of 2]
[REDACTED]

Collected [REDACTED]

—

Histopathology Report

In a few areas there is cytoplasmic clearing. There are scattered small foci suggestive of squamous differentiation in the form of larger cells with more eosinophilic cytoplasm, larger more vesicular nuclei, prominent nucleoli and sometimes multinucleation. However there is no evidence of keratinisation and no intercellular bridges are found. Mitoses are frequent and often abnormal. Immunoperoxidase staining for neuroendocrine markers (chromogranin, synaptophysin and CD56) is negative. The tumour includes endobronchial and parenchymal components. A tiny strip of metaplastic squamous epithelium showing moderate dysplasia is noted in one large bronchus adjacent to the tumour (1D), and several other airways within the tumour appear to show squamous carcinoma in situ. Vascular invasion is identified (1D, 1E) and there is invasion into, but not through, the mediastinal pleura (1E). Lymphatic invasion is not identified but metastatic carcinoma is present in peribronchial lymph nodes. No perineural invasion is seen. The bronchial resection margin is clear of dysplasia and invasive malignancy, although a small amount of largely necrotic tumour appears to lie free in the lumen. The inked mediastinal soft tissue resection margin is also clear of malignancy. The area of yellowish consolidation in the lower lobe is the result of organising obstructive pneumonitis. This shows focal cavitation resulting in the nodule noted macroscopically, but no organisms are identified in routine or special stains.

2 & 3: Sections of the separately submitted hilar and no. 8 lymph nodes show reactive lymphoid hyperplasia and aggregates of pigmented histiocytes but no evidence of metastatic carcinoma.

SUMMARY

Left pneumonectomy and lymph node sampling:

Poorly differentiated squamous cell carcinoma, 65 mm in greatest diameter.

Vascular and pleural invasion present.

No perineural invasion found.

Metastases in peribronchial lymph nodes.

Pathological stage T2 N1.

—

cc:

Lung Cancer Registry

[REDACTED]

Source: NCI Genomic Data Commons file 1b914326-bd92-4612-8760-1081214f3337 (TCGA-77-8136.BD7FBF72-BDFD-4828-9185-4DE81C426F6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).